MMRF case MMRF_1851 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9db4353c-207c-417d-a009-e40f4238c255

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 31 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.2 years (23,097 days); ISS stage: III; Days to last known disease status: 31 days; Days to last follow up: 31 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 12 days; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 13 days; Days to treatment end: 25 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 31.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 5: M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 68.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 5.5 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 28 g/L; Total Protein 10.6 g/dL; Glucose 7.15 mmol/L.
- Day 12 (ECOG 4): Hemoglobin 5.39 mmol/L; Leukocytes 7.99 ×10⁹/L; Absolute Neutrophil 4.87 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 24 g/L.

Other clinical attributes
- Day 5: Weight: 50 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1851_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 5 days.
- Sample MMRF_1851_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 5 days.
- Sample MMRF_1851_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 5 days.
